Gene-level copy-number profile of tumor specimen TARGET-20-PARIEG-09A from TARGET case TARGET-20-PARIEG, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 13.4 years (4,881 days).
Specimen TARGET-20-PARIEG-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-AML.eb28887c-b12f-53cd-af90-0835214c5ff9.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-20-PARIEG-14A (bone marrow normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 349 have no estimate.
https://portal.gdc.cancer.gov/files/1a8e1cd8-00be-4dcb-96f4-fe3d2181b4c8

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 520; copy number 1: 35; copy number 2: 57,202; copy number 3: 2,513; copy number 4: 3; copy number 5: 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:112,446,575–112,457,993, 1 gene, copy number 5: AC024996.1.

Autosomal genes at a single copy (total copy number 1): 35. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
